Somatic mutation profile of tumor specimen 0DTYB2 from CCDI case PBCJBY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.7 years (5,352 days).
Specimen 0DTYB2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58df8f43-80c1-477b-9abd-09bc94941e75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYAS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aabf6909-1392-4a0e-8e71-c3244dd97adf

The open-access MAF lists 14 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, Silent 4, Missense Mutation 2, 3'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.2644C>T p.P882S (on ENST00000611781; = p.P826S on NM_052997.2) | Missense Mutation (SNP) | VAF 43/737 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); catalogued as rs1219901612; called by muse, mutect2
- DCX | c.851del p.P284Qfs*65 (on ENST00000636035 / NM_001195553.2; = p.P284Qfs*121 on NM_000555.3) | Frame Shift Del (DEL) | VAF 118/570 reads (21%) | called by mutect2, varscan2
- XDH | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 119/580 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- IGF2R | c.31C>T p.L11= | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as rs1472235543; called by muse, mutect2, varscan2
- NOBOX | c.402C>T p.S134= | Silent (SNP) | VAF 86/513 reads (17%) | called by muse, mutect2, varscan2
- UGT1A7 | c.612G>A p.K204= | Silent (SNP) | VAF 88/611 reads (14%) | catalogued as rs147392032; called by muse, mutect2, varscan2
- ZNF248 | c.351T>C p.D117= | Silent (SNP) | VAF 59/370 reads (16%) | catalogued as rs549164170; called by muse, mutect2, varscan2
- AKR7L | c.215-53T>C | Intron (SNP) | VAF 8/122 reads (7%) | catalogued as COSV70167427; called by muse, mutect2
- C1S | c.5+99C>T | Intron (SNP) | VAF 10/112 reads (9%) | catalogued as rs1026641562; called by muse, mutect2
- COLEC11 | c.-26-728A>G | Intron (SNP) | VAF 28/373 reads (8%) | called by muse, mutect2
- HEPACAM2 | c.*71G>T | 3'UTR (SNP) | VAF 62/332 reads (19%) | called by mutect2, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 6/33 reads (18%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as COSV55814242; called by muse, mutect2
- RGS11 | c.319-49G>A | Intron (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
